Somatic mutation profile of tumor specimen TCGA-AQ-A7U7-01A (aliquot TCGA-AQ-A7U7-01A-22D-A351-09) from TCGA case TCGA-AQ-A7U7, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 55.4 years (20,239 days).
Specimen TCGA-AQ-A7U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 182ea067-eeed-4989-8529-6c60340144cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AQ-A7U7-10A (Blood Derived Normal), aliquot TCGA-AQ-A7U7-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8be6d7e-b71d-4d5f-bc9e-ee36456bab1d

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 39, Silent 17, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1, Splice Region 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14292C>A p.F4764L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV101291137; called by muse, mutect2
- BBS2 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as rs532361142, CM033337, COSV55325500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPI | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs927642824, COSV54504082; called by muse, mutect2
- CGN | c.1016T>C p.L339S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99641718; called by muse, mutect2
- COL20A1 | c.2143G>A p.V715I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200875270; called by muse, mutect2, varscan2
- CUBN | c.1233C>T p.D411= | Splice Region (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100911871; called by muse, mutect2
- DDX17 | c.1427A>G p.D476G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99318506; called by muse, mutect2, varscan2
- DMWD | c.1929G>C p.Q643H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.948); catalogued as COSV99352618; called by muse, mutect2, varscan2
- EPM2AIP1 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1165743932, COSV99212292; called by muse, mutect2
- EVL | c.191C>G p.S64* (on ENST00000402714 / NM_001330221.2; = p.S66* on NM_016337.3) | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV101233029; called by muse, mutect2, varscan2
- FAT2 | c.4039C>G p.L1347V | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV99941320; called by muse, mutect2
- FGL1 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as rs1309675350, COSV101112406; called by muse, mutect2, varscan2
- GBA | c.46A>G p.S16G | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1141804, COSV100516170; called by muse, mutect2
- GEMIN2 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99158005; called by muse, mutect2
- GFOD1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1327890092, COSV64954584; called by muse, mutect2, varscan2
- GLRA2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs777077152, COSV54341910; called by muse, mutect2
- GRAMD2B | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99586882; called by muse, mutect2
- IARS2 | c.750-1G>T p.X250_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100228024; called by muse, mutect2
- INPP5D | c.3170C>T p.S1057L (on ENST00000445964 / NM_001017915.3; = p.S1056L on NM_005541.5) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs758989076, COSV100856444; called by muse, mutect2, varscan2
- ITPKC | c.1994G>A p.G665D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99648374; called by muse, mutect2
- JAKMIP2 | c.2344C>T p.Q782* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99507083; called by muse, mutect2, varscan2
- MARCHF7 | c.1571C>G p.A524G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as COSV52027258, COSV99373416; called by muse, mutect2, varscan2
- MYH9 | c.3086T>C p.I1029T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV53387933; called by muse, mutect2, varscan2
- NUP62 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV61311277, COSV61312423; called by muse, mutect2
- PAK5 | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV100780952; called by muse, mutect2, varscan2
- PALD1 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV99697824; called by muse, mutect2
- PCDHB7 | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.361); catalogued as COSV99175202; called by muse, mutect2
- PHF3 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012740; called by muse, mutect2
- PIK3CA | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV55891897; called by muse, mutect2, varscan2
- PNKD | c.449A>T p.D150V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV99282117; called by muse, mutect2
- POF1B | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53135627, COSV99425866; called by muse, mutect2, varscan2
- PSD4 | c.1924T>G p.F642V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV99830738; called by muse, mutect2
- SIGLEC11 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.158); catalogued as COSV101388989; called by muse, mutect2, varscan2
- TBX3 | c.477_478insA p.D160Rfs*5 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | catalogued as COSV99984066; called by mutect2, pindel*
- THAP9 | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100155646; called by muse, mutect2
- TRIM60 | c.1292T>C p.M431T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1282617839, COSV61970948; called by muse, mutect2
- UCP2 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV60104308; called by muse, mutect2
- WAC | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100610825; called by muse, mutect2
- ZC3H12C | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53707024, COSV99584536; called by muse, mutect2, varscan2
- ZNF141 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV99549271; called by muse, mutect2
- ZNF208 | c.2363G>C p.R788P | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.429); catalogued as COSV101236630, COSV68111391; called by muse, mutect2, varscan2
- ZNF473 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs767908899, COSV99568418; called by muse, mutect2, varscan2
- ZNF770 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as COSV100695775; called by muse, mutect2
- NAT10 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- PANX1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); called by muse, mutect2
- PKP2 | c.385del p.Q129Sfs*13 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- SOX9 | c.253dup p.D85Gfs*167 | Frame Shift Ins (INS) | VAF 17/124 reads (14%) | called by mutect2, pindel, varscan2
- WASHC2A | c.2354C>T p.S785L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.311); called by mutect2, varscan2
- ALKBH4 | c.609C>A p.L203= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99479094; called by muse, mutect2
- BCL3 | c.336C>T p.P112= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99377912; called by muse, mutect2, varscan2
- C11orf16 | c.801C>T p.L267= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- GABRB3 | c.495C>G p.L165= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100157658; called by muse, mutect2, varscan2
- HEPHL1 | c.159C>T p.F53= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100243350; called by muse, mutect2
- MACROH2A1 | c.918G>A p.L306= (on ENST00000510038; = p.L305= on NM_004893.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV100427498; called by muse, mutect2, varscan2
- MARF1 | c.3237C>T p.P1079= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100705563; called by muse, mutect2
- MUSK | c.15C>T p.V5= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99503508; called by muse, mutect2, varscan2
- RFX7 | c.1128G>A p.V376= (on ENST00000559447 / NM_001368074.1; = p.V473= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV100428039; called by muse, mutect2, varscan2
- SLC12A3 | c.3018C>T p.I1006= (on ENST00000563236 / NM_001126108.2; = p.I1015= on NM_000339.3) | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV99343701; called by muse, mutect2, varscan2
- SPEN | c.7686C>T p.V2562= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV101004939; called by muse, mutect2
- TARBP1 | c.3600C>T p.F1200= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as rs1399954658, COSV50178441, COSV50195581; called by muse, mutect2
- THAP9 | c.1809G>A p.L603= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100155652; called by muse, varscan2
- TMOD2 | c.684G>A p.V228= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99987554; called by muse, mutect2, varscan2
- USP40 | c.1452G>A p.L484= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as rs981790837; called by muse, mutect2
- WDR1 | c.1179C>T p.L393= (on ENST00000382452; = p.L253= on NM_005112.5) | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ZNF781 | c.813C>G p.L271= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV62200116; called by muse, mutect2, varscan2
